Somatic mutation profile of tumor specimen TARGET-20-PANTPW-09A (aliquot TARGET-20-PANTPW-09A-03D) from TARGET case TARGET-20-PANTPW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (821 days).
Specimen TARGET-20-PANTPW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ee99d77-bdf8-47a6-8b2a-7093c8a276a9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANTPW-14A (Bone Marrow Normal), aliquot TARGET-20-PANTPW-14A-03D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e750743-bc01-4301-875e-56c7eaedaa30

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.923_925dup p.V308dup | In Frame Ins (INS) | VAF 42/113 reads (37%) | hotspot (GDC flag); catalogued as COSV57195593, COSV57196047, COSV57197741; called by mutect2, pindel, varscan2
- GATA2 | c.950A>T p.N317I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62003828, COSV62004430; called by muse, mutect2, varscan2
